Surgical pathology report (de-identified scan), TCGA case TCGA-BA-6868, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-6868-01B (Primary Tumor).

SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A: Larynx, right aryepiglottic fold, biopsy

- Invasive moderate to poorly differentiated keratinizing squamous cell carcinoma.

B: Larynx, right pyriform sinus, biopsy

- Invasive moderate to poorly differentiated keratinizing squamous cell carcinoma.

Clinical History:

The patient is a [REDACTED] with T3N3M0 squamous cell carcinoma of the [REDACTED] ttic fold extending into the medial right pyriform sinus.

Gross Description:

Received are two appropriately labeled containers.

Specimen A:

SITE: Right aryepiglottic fold

METHOD: Biopsy

MEASURE: 1.7 x 0.9 x 0.3 cm

COMMENT: Aggr te of multiple friable pink/tan tissue fragments

BLOCK #: A1, [REDACTED]

Specimen B:

SITE: Right pyriform sinus

METHOD: Biopsy

MEASURE: 1.4 x 0.3 x 0.3 cm

COMMENT: Aggr ate of multiple red/tan tissue fragments

BLOCK#: B1, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

Source: NCI Genomic Data Commons file 670953eb-4f23-4753-b7cc-4ebaaf26de76 (TCGA-BA-6868.534FBCCA-59E1-4219-B807-C6B177EA1DBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).